Somatic mutation profile of tumor specimen 0DGMHL from CCDI case PBBRNA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infantile fibrosarcoma; Tissue or organ of origin: Jejunum; Age at diagnosis: 0.0 years (1 days).
Specimen 0DGMHL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 424c16a2-e928-4c64-a569-92777bb8e959.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGMI4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99429b12-0bea-44c1-9c93-4d8b72651715

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1CC1 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 38/833 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- EVI5 | c.*48A>T | 3'UTR (SNP) | VAF 10/108 reads (9%) | catalogued as COSV64826922; called by muse, mutect2
